TCGA case TCGA-FU-A3HZ — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6ff12a54-10da-4941-bfea-7b66e19b4be9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, large cell, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 64.5 years (23,565 days); Year of diagnosis: 2010; Method of diagnosis: Dilation and Curettage Procedure; AJCC pathologic T: T2a2; AJCC pathologic N: N0; AJCC pathologic M: M0; FIGO stage: Stage IIA2; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Uterus.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 9; Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 53 days; Days to treatment end: 114 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 66 days; Days to treatment end: 114 days; Treatment dose: 4,500 cGy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 106 days; Days to treatment end: 120 days; Treatment dose: 1,500 cGy; Treatment outcome: Complete Response; Number of fractions: 3; Treatment anatomic sites: Primary Tumor Field.

Follow-up (7 entries)
- Day -7 (preoperative): Days to imaging: -7 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Day -7 (preoperative): Days to imaging: -7 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day -7 (preoperative): Days to imaging: -7 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day -7 (preoperative): Days to imaging: -7 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease.
- Days to follow up: 31 days; Disease response: Tumor Free.
- Days to follow up: 758 days (2.1 years); ECOG performance status: 0.
- Days to follow up: 1,103 days (3.0 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.
- Timepoint category: Initial Diagnosis; Weight: 66 kg; Height: 165 cm; BMI: 24.2.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Live Birth.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FU-A3HZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 16 mg.
  Slide TCGA-FU-A3HZ-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FU-A3HZ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FU-A3HZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 0; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Pregnant at diagnosis: No; Total pregnancy count: 0; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: curettage; Lymph nodes examined: Yes; Lymphovascular invasion: Present; Corpus involvement: Present.
- Diagnostic ct result outcomes: Ct scan preop results: Bladder Absent; Ct scan preop results: Extra-Pelvic Metastatic Disease Absent; Ct scan preop results: Parametrium Absent; Ct scan preop results: Pelvic Nodes Absent.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Performance status other timing: Follow-up Office Visit; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form, Treatment, Radiation therapy info: Brachytherapy type: HDR; Radiation therapy xrt type: External beam radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,103 days; disease-specific survival: no event (censored), 1,103 days; disease-free interval: no event (censored), 1,103 days; progression-free interval: no event (censored), 1,103 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FU-A3HZ-01A-11D-A20T-01): tumor purity 0.81, ploidy 2, whole-genome doublings 0.
